Somatic mutation profile of tumor specimen TCGA-B9-A8YH-01A (aliquot TCGA-B9-A8YH-01A-11D-A36X-10) from TCGA case TCGA-B9-A8YH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.2 years (19,051 days).
Specimen TCGA-B9-A8YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5384ef7-6d7b-4b5e-9c3e-f726816ac740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A8YH-10A (Blood Derived Normal), aliquot TCGA-B9-A8YH-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b166b1a-924d-4bcd-b0f7-65769444dd46

The open-access MAF lists 106 somatic variants for this specimen: 81 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 24, Frame Shift Del 10, Frame Shift Ins 3, Nonsense Mutation 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100741866; called by muse, mutect2, varscan2
- ADRA2A | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV99701776; called by muse, mutect2, varscan2
- ALDH1A3 | c.883+1G>C p.X295_splice | Splice Site (SNP) | VAF 44/100 reads (44%) | catalogued as COSV100320683; called by muse, mutect2, varscan2
- AQP12B | c.386A>T p.H129L (on ENST00000621682; = p.H141L on NM_001102467.2) | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101315924; called by muse, mutect2, varscan2
- ARID5B | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99690343; called by muse, mutect2, varscan2
- ASPH | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV100727758; called by muse, mutect2, varscan2
- BLK | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs765924109, COSV99377551; called by muse, mutect2, varscan2
- CARD14 | c.2500C>A p.P834T | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100413578; called by muse, mutect2, varscan2
- CCDC117 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV50770883, COSV99968946; called by muse, mutect2, varscan2
- CCDC66 | c.1654A>G p.I552V (on ENST00000394672 / NM_001353147.1; = p.I518V on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 423/799 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100414304; called by muse, mutect2, varscan2
- CCNF | c.1178T>A p.M393K | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99564087; called by muse, mutect2, varscan2
- CDON | c.2545-2A>G p.X849_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | catalogued as COSV99701906; called by muse, mutect2, varscan2
- CELF1 | c.1236T>G p.F412L (on ENST00000358597 / NM_001376422.1; = p.F408L on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100137194; called by muse, mutect2, varscan2
- CENPI | c.605G>C p.C202S | Missense Mutation (SNP) | VAF 133/180 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV99515772; called by muse, mutect2, varscan2
- CHAD | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99366312; called by muse, mutect2, varscan2
- CLECL1 | c.330T>G p.F110L | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as COSV100590133; called by muse, mutect2, varscan2
- CLN3 | c.649G>T p.G217W (on ENST00000360019 / NM_001286104.2; = p.G241W on NM_000086.2) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100343648; called by muse, mutect2, varscan2
- CPEB3 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99800461; called by muse, mutect2, varscan2
- CSTF1 | c.183T>G p.D61E | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99410335; called by muse, mutect2, varscan2
- D2HGDH | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100344896; called by muse, mutect2, varscan2
- DDX31 | c.1915T>C p.Y639H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100936873; called by muse, mutect2, varscan2
- DELE1 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519999; called by muse, mutect2, varscan2
- DERL2 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs767267573, COSV99342421; called by muse, mutect2, varscan2
- DHX16 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100906143; called by muse, mutect2, varscan2
- EAPP | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs780616368, COSV99164263; called by muse, mutect2, varscan2
- FASTKD2 | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV99379214; called by muse, mutect2, varscan2
- FBL | c.368T>G p.V123G | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99695405; called by muse, mutect2, varscan2
- GCNT3 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101251865; called by muse, mutect2
- GOLGB1 | c.8132A>T p.D2711V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100511443; called by muse, mutect2, varscan2
- GPBP1L1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99322665; called by muse, mutect2, varscan2
- HEXB | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99784450; called by muse, mutect2, varscan2
- IPO8 | c.338T>C p.M113T | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99805616; called by muse, mutect2, varscan2
- LNPEP | c.1257G>T p.L419F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99183599; called by muse, mutect2, varscan2
- LRBA | c.5972G>A p.R1991H | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277639509, COSV100842032; called by muse, mutect2, varscan2
- MICAL3 | c.2044A>G p.R682G | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99262731; called by muse, mutect2, varscan2
- MYBPC3 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99909223; called by muse, mutect2, varscan2
- MYO6 | c.3466T>G p.S1156A (on ENST00000369981; = p.S1146A on NM_004999.4) | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.12); catalogued as COSV64121807; called by muse, mutect2, varscan2
- NPHP4 | c.1910G>C p.C637S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100977114; called by muse, mutect2, varscan2
- NXPH4 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV100197364; called by muse, mutect2, varscan2
- OR10S1 | c.866T>A p.F289Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101602504; called by muse, mutect2, varscan2
- PATZ1 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99315609; called by muse, mutect2, varscan2
- PDE4DIP | c.3295C>A p.Q1099K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as rs782502294, COSV100521388; called by mutect2, varscan2
- PKP1 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1363541582, COSV99825662; called by muse, mutect2, varscan2
- POU2F1 | c.420C>G p.H140Q (on ENST00000541643 / NM_001365848.1; = p.H163Q on NM_002697.4) | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.969); catalogued as COSV99611981; called by muse, mutect2, varscan2
- PSMA1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV101123695; called by muse, varscan2
- PTGER3 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100139553; called by muse, mutect2, varscan2
- PTTG1IP | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100445958; called by muse, mutect2, varscan2
- PYCR3 | c.191A>C p.E64A | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV99643654; called by muse, mutect2, varscan2
- PYROXD2 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100996105; called by muse, mutect2
- RGL4 | c.864G>C p.R288S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV99318897; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | catalogued as rs759765382; called by mutect2, varscan2
- RPS27 | c.185T>A p.V62D | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99668894; called by muse, mutect2, varscan2
- RTEL1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs758245234, COSV100542775; called by muse, mutect2, varscan2
- SERPINA12 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100369795; called by muse, mutect2, varscan2
- SGK1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99399042; called by muse, mutect2, varscan2
- SLC2A12 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99260481; called by muse, mutect2, varscan2
- SLC44A2 | c.403T>G p.Y135D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1192528269, COSV100212910, COSV100213436; called by muse, mutect2, varscan2
- SLITRK1 | c.1948A>C p.K650Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV101000034; called by muse, mutect2, varscan2
- THEM4 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100916964; called by muse, mutect2, varscan2
- TMIGD3 | c.603A>T p.K201N (on ENST00000369717 / NM_001081976.2; = p.K282N on NM_020683.7) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100778427; called by muse, mutect2, varscan2
- TMPRSS6 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100696100; called by muse, mutect2, varscan2
- TNS4 | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as COSV99564100; called by muse, mutect2, varscan2
- TTN | c.81560A>G p.Q27187R (on ENST00000591111; = p.Q19763R on NM_003319.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | PolyPhen benign (0.178); catalogued as rs1412211195, COSV100627057; called by muse, mutect2, varscan2
- UBR4 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as rs775608879, COSV100921664; called by muse, mutect2, varscan2
- UNC13B | c.3091G>A p.A1031T | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1276738074, COSV101037195; called by muse, mutect2, varscan2
- WAPL | c.3508T>C p.C1170R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV99556601; called by muse, mutect2, varscan2
- XRN2 | c.1346C>G p.P449R | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV101018583; called by muse, mutect2, varscan2
- ARSL | c.606del p.V203Sfs*10 | Frame Shift Del (DEL) | VAF 96/159 reads (60%) | called by mutect2, pindel, varscan2
- CHST2 | c.600del p.W201Gfs*20 | Frame Shift Del (DEL) | VAF 90/143 reads (63%) | called by mutect2, pindel*, varscan2
- CRYBA1 | c.372dup p.K125* | Frame Shift Ins (INS) | VAF 115/228 reads (50%) | called by mutect2, pindel, varscan2
- CSMD1 | c.288del p.N97Ifs*2 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- IRF2BP1 | c.1155dup p.E386Rfs*30 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- NEK2 | c.1312del p.S438Afs*21 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | called by mutect2, pindel, varscan2
- NOCT | c.521_540del p.E174Gfs*9 | Frame Shift Del (DEL) | VAF 43/136 reads (32%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.3246del p.G1083Afs*64 | Frame Shift Del (DEL) | VAF 28/49 reads (57%) | called by mutect2, pindel, varscan2
- RAP1GDS1 | c.1814_1815del p.V605Gfs*15 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by pindel, varscan2
- SCGB2B2 | c.100_101del p.V34Cfs*3 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- SLC12A7 | c.657del p.T220Pfs*6 | Frame Shift Del (DEL) | VAF 70/235 reads (30%) | called by pindel, varscan2
- SLC12A7 | c.648T>A p.Y216* | Nonsense Mutation (SNP) | VAF 78/208 reads (38%) | called by muse, varscan2
- SYNRG | c.3553G>C p.E1185Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF2 | c.140del p.G47Dfs*5 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ADAM15 | c.2466G>A p.L822= (on ENST00000356955 / NM_207197.3; = p.L773= on NM_003815.5) | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV99665279; called by muse, mutect2, varscan2
- ARHGAP1 | c.858C>T p.N286= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs758948520, COSV61735967; called by muse, mutect2, varscan2
- AUTS2 | c.1887C>T p.L629= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV100719443; called by muse, mutect2, varscan2
- CBLN4 | c.51C>T p.V17= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs748057543, COSV99290710; called by muse, mutect2, varscan2
- CEP192 | c.6978T>C p.F2326= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs1402913215, COSV100381961; called by muse, mutect2, varscan2
- CKAP5 | c.5313A>G p.K1771= (on ENST00000529230 / NM_001008938.4; = p.K1711= on NM_014756.3) | Silent (SNP) | VAF 4/89 reads (4%) | catalogued as COSV56368320; called by muse, mutect2
- EP300 | c.4851T>C p.P1617= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs749139417, COSV99609604; called by muse, mutect2, varscan2
- EPG5 | c.4575T>G p.A1525= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99957979; called by muse, mutect2, varscan2
- ERCC6L2 | c.1344C>T p.Y448= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs1349123863, COSV99998944; called by muse, mutect2, varscan2
- F13B | c.924C>A p.I308= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as COSV66374065; called by muse, mutect2, varscan2
- LRP2 | c.3819A>G p.S1273= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV99789999; called by muse, mutect2, varscan2
- OGFRL1 | c.1155C>T p.S385= | Silent (SNP) | VAF 143/358 reads (40%) | catalogued as COSV100965799; called by muse, mutect2, varscan2
- PHF3 | c.1518G>A p.P506= | Silent (SNP) | VAF 114/291 reads (39%) | catalogued as COSV50313124; called by muse, mutect2, varscan2
- PRG4 | c.2919T>C p.I973= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV100798306; called by muse, mutect2, varscan2
- PTGER3 | c.177G>T p.L59= | Silent (SNP) | VAF 83/249 reads (33%) | catalogued as rs1440514390, COSV100139556; called by muse, mutect2, varscan2
- SBF1 | c.3082T>C p.L1028= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100817994; called by muse, mutect2, varscan2
- SCN5A | c.5611C>T p.L1871= (on ENST00000333535 / NM_198056.3; = p.L1870= on NM_000335.5) | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV100350262; called by muse, mutect2, varscan2
- SHROOM4 | c.606T>C p.C202= | Silent (SNP) | VAF 67/81 reads (83%) | catalogued as COSV99174421; called by muse, mutect2, varscan2
- SLFN11 | c.2128T>C p.L710= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV100390963, COSV57699636; called by muse, mutect2, varscan2
- SRSF6 | c.363C>T p.C121= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV99719825; called by muse, mutect2, varscan2
- STYX | c.354G>C p.V118= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100648329; called by muse, mutect2, varscan2
- TFR2 | c.333C>T p.C111= | Silent (SNP) | VAF 75/159 reads (47%) | catalogued as rs767726878, COSV99355723; called by muse, mutect2, varscan2
- WNK1 | c.2496T>C p.P832= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as COSV100268408; called by muse, mutect2, varscan2
- ZNF467 | c.1089C>T p.S363= | Silent (SNP) | VAF 124/264 reads (47%) | catalogued as rs1032948685, COSV57372003; called by muse, mutect2, varscan2
- NOP56 | c.570-167_570-161del | Intron (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
